Surgical pathology report (de-identified scan), TCGA case TCGA-MH-A854, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MH-A854-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

ICD-O-3
Carcinoma, papillary renal
cell 826013
Site: R Kidney NOS 0649
11/29/13

PATHOLOGIC DIAGNOSIS

A: KIDNEY, RIGHT MID LATERAL, TUMOR, PARTIAL NEPHRECTOMY:

- PAPILLARY RENAL CELL CARCINOMA, TYPE II (4.5 CM)
- FUHRMAN NUCLEAR GRADE 3
- RENAL PARENCHYMAL MARGIN INVOLVED BY INVASIVE CARCINOMA
- SEE SYNOPTIC REPORT, BELOW

B: KIDNEY, RIGHT LOWER, TUMOR, RESECTION:

- PAPILLARY RENAL CELL CARCINOMA, TYPE II (1.4 CM)
- FUHRMAN NUCLEAR GRADE 2
- RENAL PARENCHYMAL MARGIN INVOLVED BY INVASIVE CARCINOMA
- RENAL CAPSULAR MARGIN APPEARS UNINVOLVED

C: KIDNEY, RIGHT MID ANTERIOR, TUMOR, BIOPSY:

- PAPILLARY RENAL CELL CARCINOMA, TYPE II
- FUHRMAN NUCLEAR GRADE 2
- TUMOR SIZE: APPROXIMATELY 0.8 CM (SEE COMMENT)

D: KIDNEY, RIGHT SUPERIOR LATERAL, TUMOR, BIOPSY:

- PAPILLARY RENAL CELL CARCINOMA, TYPE I
- FUHRMAN NUCLEAR GRADE 1
- TUMOR SIZE: APPROXIMATELY 0.1 CM (SEE COMMENT)

E: KIDNEY, RIGHT UPPER MEDIAL, LESION, BIOPSY:

- PAPILLARY RENAL CELL CARCINOMA, TYPE II
- FUHRMAN NUCLEAR GRADE 2
- TUMOR SIZE: APPROXIMATELY 0.5 CM (SEE COMMENT)

SYNOPTIC REPORT:

- PAPILLARY RENAL CELL CARCINOMA, TYPE II, FUHRMAN NUCLEAR GRADE 3
- TUMOR FOCALITY: MULTIFOCAL
- TUMOR SIZE: 4.5 X 4 X 2.5 CM (LARGEST TUMOR, PART A)
- MACROSCOPIC EXTENT OF TUMOR: TUMOR LIMITED TO KIDNEY
- MICROSCOPIC TUMOR EXTENSION: TUMOR LIMITED TO KIDNEY
- SARCOMATOID FEATURES: NOT IDENTIFIED
- TUMOR NECROSIS: NOT IDENTIFIED
- LYMPH-VASCULAR INVASION: NOT IDENTIFIED
- MARGINS:
- RENAL PARENCHYMAL MARGIN INVOLVED BY INVASIVE CARCINOMA

[page 2 of 3]
- RENAL CAPSULAR MARGIN: APPEARS UNINVOLVED
- PERINEPHRIC FAT MARGIN: NOT APPLICABLE
- PATHOLOGIC FINDINGS IN NONNEOPLASTIC KIDNEY:
- APPROXIMATELY 5% GLOMERULOSCLEROSIS
- FOCAL TUBULAR ATROPHY WITH ENDOCRINIZATION
- MODERATE ARTERIOLOSCLEROSIS
- OTHER TUMORS:
- MULTIFOCAL PAPILLARY RENAL CELL CARCINOMA
- SEE PARTS B-E, ABOVE
- PATHOLOGIC STAGING:
- TNM DESCRIPTORS: m (MULTIPLE PRIMARY TUMORS)
- PRIMARY TUMOR: pT(m)1b (TUMOR 4-7 CM IN GREATEST DIMENSION, LIMITED TO THE KIDNEY)
- REGIONAL LYMPH NODES: pNX (NO NODES SUBMITTED OR FOUND)
- DISTANT METASTASIS: NOT APPLICABLE

Staff Pathologist

COMMENT: The tissue submitted in parts C-E was fragmented; adequate assessment of surgical margin and accurate tumor size is not possible.

Gross Description

Specimen Material: A. Renal, R mid lateral tumor:

B. Renal, R lower pole tumor:

C. Renal, R mid anterior tumor:

D. Renal, R superior lateral tumor:

E. Renal, R upper medial lesion:

Part A: The specimen is received in formalin, labeled "RIGHT MID LATERAL RENAL TUMOR", and consists of a 28 gram well-circumscribed, circular mass (4.5 x 4 x 2.5 cm). One side of the renal mass has a rim of normal-appearing, tan-gray renal parenchyma; the other side is an encapsulated firm mass. The specimen is serially sectioned, and the cut surface shows a friable, hemorrhagic, yellow mass that does not appear to extend through the renal capsule. The tumor abuts the inked resection margin. A portion of this tumor is submitted for further studies (tissue banking).

Ink Code:

[page 3 of 3]
Resection margin of kidney orange

Cassette Code:

A1-8: Inked renal resection margin with adjacent tumor (resection margin entirely submitted)

A9: uninvolved renal parenchyma

Part B: The specimen is received in formalin, labeled "RIGHT LOWER LOBE RENAL TUMOR", and consists of a single tan-gray nodule (1.7 x 1.5 x 0.7 cm). The cut surface shows a hemorrhagic yellow nodule. The specimen is serially sectioned and entirely submitted in B1-2.

Part C: The specimen is received in formalin, labeled "RIGHT ANTERIOR MID LESION RENAL TUMOR", and consists of two tan-gray nodules (1.2 x 0.6 x 0.4 cm in aggregate). The specimen is entirely submitted in cassette C1.

Part D: The specimen is received in formalin, labeled "RIGHT SUPERIOR LATERAL RENAL TUMOR", and consists of two tan-gray fragments of tissue (1.8 x 1.4 x 0.4 cm in aggregate). The specimen is submitted entirely in D1.

Part E: The specimen is received in formalin, labeled "RIGHT UPPER MEDIAL RENAL LESION", and consists of multiple fragments of tan-gray tissue (0.9 x 0.7 x 0.3 cm in aggregate). The specimen is entirely submitted in cassette E1.

Pathology Resident

Microscopic Description

A-E: Performed.

Intradepartmental consultation: _____ has examined this case and agrees with the findings and interpretation.

The staff pathologist listed below has reviewed this case.

****Electronically Signed Out****

Staff Pathologist

Criteria	W	10/21/13	Yes	No

Source: NCI Genomic Data Commons file 3fc609de-8844-4582-a971-bbc1ea1ce99a (TCGA-MH-A854.E57FFF7C-7AE1-43F0-9C72-E0C287CF2B3A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).